Somatic mutation profile of tumor specimen TCGA-DK-AA76-01A (aliquot TCGA-DK-AA76-01A-11D-A391-08) from TCGA case TCGA-DK-AA76, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.5 years (23,542 days).
Specimen TCGA-DK-AA76-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6af030cd-ead0-46a7-893f-a153d6b6195f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA76-10A (Blood Derived Normal), aliquot TCGA-DK-AA76-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aae8226b-8965-433e-bacb-671421f0891b

The open-access MAF lists 276 somatic variants for this specimen: 208 protein-altering or splice-affecting, 61 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 61, Nonsense Mutation 19, Splice Site 7, RNA 3, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 2, In Frame Del 2, Splice Region 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA0586 | c.2308C>T p.R770* (on ENST00000619416 / NM_001244190.2; = p.R709* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 54/62 reads (87%) | catalogued as rs1064793157, CM1510289, COSV99708287; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 37/67 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD15 | c.1338G>C p.Q446H | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56194661; called by muse, mutect2, varscan2
- ACSL5 | c.1346C>T p.T449I (on ENST00000354273; = p.T505I on NM_016234.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV61129340; called by muse, mutect2, varscan2
- ACTB | c.1006A>T p.K336* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as COSV100079702; called by muse, mutect2, varscan2
- ADAMTS12 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV61257453; called by muse, mutect2, varscan2
- ADCY5 | c.1851C>G p.D617E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV59195285; called by muse, mutect2, varscan2
- ADD2 | c.1537G>C p.A513P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV52456303; called by muse, mutect2, varscan2
- ADGRF5 | c.1503G>C p.E501D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.63); catalogued as COSV51930872; called by muse, mutect2, varscan2
- ADGRF5 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.035); catalogued as COSV51930877; called by muse, mutect2
- ADORA3 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV53985239; called by muse, varscan2
- AHR | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54122150; called by muse, mutect2, varscan2
- AKAP9 | c.4339-1G>A p.X1447_splice | Splice Site (SNP) | VAF 22/46 reads (48%) | catalogued as COSV62340713; called by muse, mutect2, varscan2
- AL645922.1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | catalogued as COSV100191166, COSV54960036; called by muse, mutect2, varscan2
- ALG10 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56791937; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4300G>C p.E1434Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV51842322; called by muse, mutect2, varscan2
- ANXA7 | c.1345-1G>C p.X449_splice (on ENST00000372919 / NM_001320880.2; = p.X427_splice on NM_001156.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV65823129; called by muse, mutect2, varscan2
- APOB | c.3297G>C p.K1099N | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV51926733; called by muse, mutect2, varscan2
- APOC4 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV52989986; called by muse, mutect2, varscan2
- AQR | c.2614G>C p.D872H | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50030175; called by muse, mutect2, varscan2
- ARID2 | c.4468G>T p.G1490* | Nonsense Mutation (SNP) | VAF 39/80 reads (49%) | catalogued as rs1174556277, COSV100536340; called by muse, mutect2, varscan2
- ARL8A | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV55342837; called by muse, mutect2, varscan2
- ASB11 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 72/225 reads (32%) | catalogued as rs1387146962, COSV100729049; called by muse, mutect2, varscan2
- ATG5 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1450101861, COSV58346486; called by muse, mutect2, varscan2
- ATP13A2 | c.1991G>A p.C664Y | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1224351966, COSV58698612; called by muse, mutect2, varscan2
- ATP13A2 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs750921184, COSV58698621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2A | c.2987T>C p.L996P | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1277690041, COSV51633096; called by muse, mutect2, varscan2
- BAZ2B | c.284T>A p.L95H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58596886; called by muse, mutect2, varscan2
- BDP1 | c.3886G>A p.E1296K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV62429621; called by muse, mutect2, varscan2
- BEST2 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV50359790; called by muse, mutect2, varscan2
- BPIFB6 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV62754490; called by muse, mutect2, varscan2
- BPTF | c.9109C>G p.H3037D | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs782703860, COSV58832953; called by muse, mutect2, varscan2
- BRD7 | c.1366C>G p.P456A | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.763); catalogued as COSV67158322, COSV67158407, COSV67158510; called by muse, varscan2
- BRDT | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV62863721; called by muse, mutect2, varscan2
- BRF1 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT tolerated (0.49); PolyPhen benign (0.267); catalogued as rs1263125046, COSV59266610; called by muse, mutect2, varscan2
- C12orf40 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV61129945, COSV61130057; called by muse, mutect2, varscan2
- C5 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56324686; called by muse, mutect2, varscan2
- CACNG6 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1177207677, COSV53165946; called by muse, mutect2, varscan2
- CDC23 | c.589C>G p.H197D | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV67508323; called by muse, mutect2, varscan2
- CDON | c.2213A>G p.Y738C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs149325046; called by mutect2, varscan2
- CEP63 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs777049621, COSV59674853; called by muse, mutect2, varscan2
- CFAP43 | c.1836C>G p.I612M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53376786; called by muse, mutect2, varscan2
- CHI3L1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs746382181, COSV55137359; called by muse, mutect2, varscan2
- CHRM5 | c.910A>T p.S304C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV67246894; called by muse, mutect2, varscan2
- CLCA4 | c.2041C>G p.H681D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55366890; called by muse, mutect2, varscan2
- CLK2 | c.979G>C p.D327H (on ENST00000368361 / NM_001294339.2; = p.D326H on NM_003993.4) | Missense Mutation (SNP) | VAF 59/61 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56943715, COSV56944030; called by muse, mutect2, varscan2
- CNTRL | c.2701G>C p.D901H | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53044461; called by muse, mutect2, varscan2
- COG5 | c.1529A>C p.N510T | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs1314947216, COSV51744486; called by muse, mutect2, varscan2
- CORO1A | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as CD087494, COSV54630632; called by muse, mutect2, varscan2
- DNAH1 | c.11624C>T p.T3875M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.459); catalogued as rs754430692, COSV56231623; called by muse, mutect2, varscan2
- DRAM2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV54414747; called by muse, mutect2, varscan2
- DSG2 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 49/104 reads (47%) | catalogued as COSV55196696; called by muse, mutect2, varscan2
- DUSP9 | c.1107C>G p.F369L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100720120; called by muse, mutect2
- DYNC2H1 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV62085185, COSV62088728; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.957G>A p.K319= | Splice Region (SNP) | VAF 9/87 reads (10%) | catalogued as COSV62567009; called by muse, mutect2, varscan2
- EHD1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV57733862, COSV57735225; called by muse, mutect2, varscan2
- ENPP1 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765071179, CM031968, COSV62930765, COSV62936019; called by muse, mutect2, varscan2
- EOGT | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55149775; called by muse, mutect2, varscan2
- EPHB6 | c.1927G>T p.V643L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV63890877; called by muse, mutect2, varscan2
- F13B | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100803314; called by muse, mutect2, varscan2
- FAT3 | c.5806A>T p.S1936C | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV53085151; called by muse, mutect2, varscan2
- FGFR2 | c.1977G>C p.K659N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM020143, COSV60638719, COSV60655029; called by muse, mutect2, varscan2
- FHOD3 | c.2842-1G>C p.X948_splice (on ENST00000359247 / NM_001281739.3; = p.X965_splice on NM_025135.5) | Splice Site (SNP) | VAF 45/99 reads (45%) | catalogued as COSV57166993; called by muse, mutect2, varscan2
- FIBCD1 | c.1232A>C p.Y411S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53392715; called by muse, mutect2, varscan2
- FLCN | c.185G>T p.S62I | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV53257745; called by muse, mutect2, varscan2
- FMO5 | c.641G>T p.S214I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1553923154, COSV54204910; called by muse, mutect2, varscan2
- FURIN | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51575130; called by muse, mutect2, varscan2
- GABRA4 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.343); catalogued as rs868473630, COSV51923942; called by muse, mutect2, varscan2
- GABRE | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.883); catalogued as COSV100944390, COSV64819117; called by muse, mutect2, varscan2
- GJB3 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.809); catalogued as rs1192346586, COSV64904442; called by muse, mutect2, varscan2
- GLI3 | c.2849G>A p.R950K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1243190228, COSV67886111; called by muse, mutect2, varscan2
- GPR141 | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57731590; called by muse, mutect2, varscan2
- GRIA1 | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs776926017, COSV53592638; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2185G>C p.E729Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV100736434; called by mutect2, varscan2
- HHIPL1 | c.1497G>A p.M499I | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV58089514; called by muse, mutect2, varscan2
- HPS4 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53225714; called by mutect2, varscan2
- HSPA8 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV57082942; called by muse, mutect2, varscan2
- IFIT1 | c.815A>T p.E272V | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV65661226; called by muse, mutect2, varscan2
- IGF2R | c.3326T>A p.V1109D | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV63626967; called by muse, mutect2
- IGHM | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0.01); catalogued as rs1398324382; called by muse, mutect2, varscan2
- IL22RA2 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV51662650; called by muse, mutect2, varscan2
- IP6K1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100391369, COSV58663074; called by muse, mutect2, varscan2
- JRKL | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as COSV53592480; called by muse, mutect2, varscan2
- JTB | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV55131596; called by muse, mutect2, varscan2
- KCNH6 | c.2233G>C p.G745R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59001343; called by muse, mutect2
- KCNQ3 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV66465496; called by muse, mutect2, varscan2
- KCNU1 | c.2570G>T p.R857L | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV67753864, COSV67753916; called by muse, mutect2, varscan2
- KLHL2 | c.1576G>T p.V526F | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56974622; called by muse, mutect2, varscan2
- KLHL42 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as COSV67145689; called by muse, mutect2, varscan2
- KPTN | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 143/205 reads (70%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as COSV57644205; called by muse, mutect2, varscan2
- LIM2 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 31/128 reads (24%) | catalogued as COSV99702381; called by muse, mutect2, varscan2
- LPAR6 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV57298616; called by muse, mutect2, varscan2
- LRP1B | c.10244G>T p.R3415I | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV67195929; called by muse, mutect2, varscan2
- LRP2 | c.9398T>C p.F3133S | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55544486; called by muse, mutect2, varscan2
- LRRFIP2 | c.1839T>A p.N613K | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60866551; called by muse, mutect2, varscan2
- LRSAM1 | c.321+1G>T p.X107_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as rs1356148344, COSV55938752; called by muse, mutect2, varscan2
- LSM8 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99972669; called by muse, mutect2, varscan2
- MAGI2 | c.3375C>G p.H1125Q | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV62639561; called by muse, mutect2, varscan2
- MAJIN | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57262487; called by muse, mutect2, varscan2
- MCM3AP | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52437109; called by muse, mutect2
- MDN1 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV65518444; called by muse, mutect2
- MEI1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100299911, COSV100300038; called by muse, mutect2, varscan2
- METTL3 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 70/80 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52967839; called by muse, mutect2, varscan2
- MSH6 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469561474, COSV52275770, COSV99316733; called by muse, mutect2, varscan2
- MST1R | c.1745G>C p.R582T | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV56565751; called by muse, mutect2, varscan2
- MYH9 | c.5221G>T p.E1741* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99339065; called by mutect2, varscan2
- MYO7A | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68683804; called by muse, mutect2, varscan2
- NAV1 | c.3826G>A p.V1276M | Missense Mutation (SNP) | VAF 56/61 reads (92%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as rs779420279, COSV55214897; called by muse, mutect2, varscan2
- NBEA | c.4589C>T p.P1530L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV59766467; called by muse, mutect2
- NBEAL1 | c.7133A>T p.Q2378L | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV68915703; called by muse, mutect2
- NCSTN | c.819C>A p.D273E | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54185621; called by muse, mutect2, varscan2
- NDST3 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56614360; called by muse, mutect2, varscan2
- NLRP1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs373530609; called by muse, mutect2, varscan2
- NR1D2 | c.378C>G p.F126L | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56991004; called by muse, mutect2, varscan2
- NR1H4 | c.1231T>C p.Y411H (on ENST00000551379 / NM_001206993.2; = p.Y397H on NM_005123.4) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.297); catalogued as COSV51850054; called by muse, mutect2, varscan2
- NSD1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs947867539, COSV61772067; called by muse, mutect2, varscan2
- NUP214 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100845305; called by muse, mutect2
- OBSCN | c.16597G>C p.E5533Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52749860; called by muse, mutect2, varscan2
- OR51G2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58992051; called by muse, mutect2, varscan2
- OR52A5 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.933); catalogued as COSV56614449; called by muse, mutect2, varscan2
- OTOF | c.5435A>T p.E1812V (on ENST00000272371 / NM_194248.3; = p.E1045V on NM_004802.4) | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55497920; called by muse, mutect2, varscan2
- PALB2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55163134; called by muse, mutect2, varscan2
- PAPPA | c.4162C>T p.R1388W | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs143399770; called by muse, varscan2
- PATL1 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV55688304; called by muse, mutect2, varscan2
- PAWR | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100174317, COSV99076043; called by muse, mutect2
- PBXIP1 | c.1766C>G p.S589* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100870112, COSV63776918; called by muse, mutect2
- PCDH17 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV64972495; called by muse, mutect2, varscan2
- PHEX | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV65074225; called by muse, mutect2, varscan2
- PIGA | c.848+1G>C p.X283_splice | Splice Site (SNP) | VAF 39/111 reads (35%) | catalogued as COSV61237141; called by muse, mutect2, varscan2
- PIK3CA | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 69/108 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as COSV55891819, COSV55986942; called by muse, mutect2, varscan2
- PIP4K2A | c.665G>C p.S222T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV60540223; called by muse, mutect2, varscan2
- PLCB4 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53795583, COSV53808676; called by muse, mutect2, varscan2
- PLXNB3 | c.2048A>T p.Q683L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100737503; called by muse, mutect2, varscan2
- PLXNB3 | c.2049G>T p.Q683H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781975103, COSV62795961; called by muse, mutect2, varscan2
- POLE | c.444G>C p.L148F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1060500797, COSV57675783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLN | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV67023789; called by muse, mutect2, varscan2
- POMGNT1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 41/96 reads (43%) | PolyPhen benign (0.006); catalogued as COSV64339451; called by muse, mutect2, varscan2
- POTEE | c.442T>G p.W148G | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV100388139; called by muse, mutect2, varscan2
- PPEF1 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62995284; called by muse, mutect2, varscan2
- PRRC2B | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV61934699; called by muse, mutect2, varscan2
- PTOV1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs538029470, COSV55586724; called by muse, mutect2, varscan2
- PTPRH | c.3208G>A p.V1070I | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs140496718; called by muse, mutect2, varscan2
- PTPRT | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as COSV61966249; called by muse, mutect2, varscan2
- PXDNL | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs1432085650, COSV62478278, COSV62500583; called by muse, mutect2, varscan2
- RAB11FIP2 | c.722T>A p.L241Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV62924948; called by muse, mutect2, varscan2
- RACK1 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV65174386; called by muse, mutect2, varscan2
- RANBP9 | c.574C>A p.H192N | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); catalogued as COSV50580418; called by muse, mutect2, varscan2
- RAPGEF2 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs201922456, COSV52425638; called by muse, mutect2, varscan2
- RBFOX1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs747612014, COSV60947328, COSV60981803; called by muse, mutect2, varscan2
- RBM10 | c.2332C>T p.Q778* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100237923; called by muse, mutect2, varscan2
- RBM45 | c.1414C>T p.R472W (on ENST00000616198 / NM_001365579.1; = p.R470W on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477623344, COSV53720211; called by muse, mutect2, varscan2
- RBM8A | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV57161993; called by muse, mutect2, varscan2
- RBM8A | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57161985; called by muse, varscan2
- RBSN | c.2213T>C p.L738P | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53791824; called by muse, mutect2, varscan2
- RC3H1 | c.2048G>A p.R683K | Missense Mutation (SNP) | VAF 162/177 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV51198302; called by muse, mutect2, varscan2
- RPGR | c.2959A>C p.K987Q (on ENST00000339363 / NM_001367249.1; = p.K782Q on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV58833085; called by muse, mutect2, varscan2
- RPH3A | c.632G>T p.G211V (on ENST00000389385 / NM_001143854.2; = p.G207V on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV66990251; called by muse, mutect2, varscan2
- RYR3 | c.9712G>A p.D3238N (on ENST00000389232; = p.D3239N on NM_001036.6) | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs200275874, COSV66780962; called by muse, mutect2, varscan2
- SEZ6L2 | c.2628C>G p.F876L (on ENST00000308713 / NM_001114099.3; = p.F819L on NM_012410.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.332); catalogued as COSV58097734, COSV58100284; called by muse, mutect2, varscan2
- SH3KBP1 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV65639758; called by muse, mutect2, varscan2
- SHC1 | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100460443; called by muse, mutect2, varscan2
- SOX5 | c.2101A>C p.S701R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58621750; called by muse, mutect2
- SPTBN2 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs894025675, COSV59448474; called by muse, mutect2, varscan2
- SRRM4 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs1179092789, COSV57410635; called by muse, mutect2, varscan2
- SRSF1 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99365414; called by muse, mutect2, varscan2
- SRSF4 | c.1065G>C p.K355N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV100861408; called by muse, mutect2
- STAG1 | c.1639A>T p.T547S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV52603806; called by muse, mutect2, varscan2
- STOX1 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV53813499, COSV53814632; called by muse, mutect2, varscan2
- SYNJ2 | c.3982C>G p.L1328V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.046); catalogued as COSV62895938; called by muse, mutect2, varscan2
- TCF23 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 99/205 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as rs759113306, COSV56078045; called by muse, mutect2, varscan2
- TEF | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs757179497, COSV56747387; called by muse, mutect2, varscan2
- TMEM120B | c.504C>A p.Y168* | Nonsense Mutation (SNP) | VAF 19/188 reads (10%) | catalogued as COSV100699656; called by muse, mutect2, varscan2
- TMEM8B | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs797017228, COSV65075819, COSV65077630; called by muse, mutect2, varscan2
- TMPRSS6 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as rs374472034; called by muse, mutect2, varscan2
- TOMM34 | c.170G>C p.R57P | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65688874; called by muse, mutect2, varscan2
- TRDMT1 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as COSV58318578, COSV58319857; called by muse, mutect2, varscan2
- TRIM32 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs754071735, COSV57758408; called by muse, mutect2, varscan2
- TRO | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99436601; called by muse, mutect2
- TSC2 | c.3509C>A p.S1170* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs45517296, CM078628, COSV99554354; ClinVar: not provided; called by muse, mutect2, varscan2
- TTC19 | c.831+2T>A p.X277_splice | Splice Site (SNP) | VAF 11/27 reads (41%) | catalogued as COSV51964494; called by muse, mutect2, varscan2
- TTK | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV57881684; called by muse, mutect2, varscan2
- TTN | c.25768C>T p.P8590S (on ENST00000591111; = p.P7663S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | PolyPhen benign (0); catalogued as rs764261158, COSV100592076, COSV59926132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA4A | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs985144317, COSV50277800; called by muse, mutect2
- TYRO3 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs778546483, COSV55481467; called by muse, varscan2
- UBE2T | c.249_258del p.R84Wfs*22 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as COSV66153149; called by mutect2, pindel
- UNC5C | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV71658614; called by muse, mutect2, varscan2
- USP33 | c.1927C>A p.Q643K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV62468566; called by muse, mutect2, varscan2
- VAT1L | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1567497956, COSV100213596; called by muse, varscan2
- VPS33A | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as rs1247451944, COSV57356352; called by muse, mutect2, varscan2
- VPS54 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as COSV55443523; called by muse, mutect2, varscan2
- VWF | c.461A>C p.Y154S | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV54613629; called by muse, mutect2, varscan2
- WWC3 | c.2581C>T p.Q861* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV66509424; called by muse, mutect2, varscan2
- ZCWPW1 | c.1804G>T p.V602F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52199505; called by muse, mutect2, varscan2
- ZDHHC14 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537665521, COSV58193259, COSV58193376, COSV58197486; called by muse, mutect2, varscan2
- ZEB2 | c.3574G>A p.D1192N | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); catalogued as COSV57952829; called by muse, mutect2, varscan2
- ZNF112 | c.1702C>T p.L568F (on ENST00000337401 / NM_001083335.2; = p.L562F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV61619131; called by muse, mutect2, varscan2
- ZNF224 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199525071; called by muse, mutect2
- ZNF774 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62979697; called by muse, mutect2, varscan2
- ARID1A | c.2401_2402dup p.Q802Vfs*32 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- ASH1L | c.6104-12_6126del p.X2035_splice | Splice Site (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel
- DYRK4 | c.722del p.K241Rfs*35 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by pindel, varscan2
- IGHV4-34 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MYPN | c.696_716del p.A233_E239del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- PPP2R5C | c.1057_1064del p.E353Hfs*6 | Frame Shift Del (DEL) | VAF 21/108 reads (19%) | called by mutect2, pindel, varscan2
- RNF128 | c.1079dup p.T361Dfs*14 (on ENST00000255499 / NM_194463.2; = p.T335Dfs*14 on NM_024539.3) | Frame Shift Ins (INS) | VAF 24/170 reads (14%) | called by mutect2, pindel, varscan2
- TBC1D12 | c.1_4del p.M1_?2 | Translation Start Site (DEL) | VAF 9/19 reads (47%) | called by mutect2, varscan2
- TJP1 | c.587_589del p.E197del | In Frame Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- WASHC2A | c.1202G>C p.G401A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ABCA8 | c.4002G>T p.L1334= | Silent (SNP) | VAF 48/153 reads (31%) | catalogued as COSV52196282; called by muse, mutect2, varscan2
- AHNAK2 | c.5373G>A p.V1791= | Silent (SNP) | VAF 152/455 reads (33%) | catalogued as rs751170153, COSV60909834; called by muse, varscan2
- ANKRD20A2P | c.111C>A p.I37= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV101111846; called by mutect2, varscan2
- ARFGEF3 | c.606C>G p.L202= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1473603298, COSV52451819; called by muse, mutect2, varscan2
- ATP2B2 | c.312G>A p.Q104= | Silent (SNP) | VAF 144/337 reads (43%) | catalogued as COSV59491352; called by muse, mutect2, varscan2
- CACNA1G | c.2887C>T p.L963= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1246251474, COSV61721453; called by muse, mutect2, varscan2
- CELF2 | c.615C>T p.I205= (on ENST00000416382 / NM_001025077.3; = p.I212= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/78 reads (62%) | catalogued as rs762525404, COSV59970742, COSV59974970; called by muse, mutect2, varscan2
- CES3 | c.261G>A p.V87= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1178794987, COSV57592866; called by muse, mutect2, varscan2
- CFAP126 | c.525C>G p.A175= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV61367628; called by muse, mutect2
- CHGB | c.1548G>A p.K516= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV66759758; called by muse, mutect2, varscan2
- COL16A1 | c.2571C>A p.L857= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV54701853, COSV54702316; called by muse, mutect2, varscan2
- EOMES | c.1188C>T p.Y396= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV55411461; called by muse, mutect2, varscan2
- FLNC | c.3726C>A p.V1242= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV57951979, COSV57954530; called by muse, mutect2, varscan2
- FN1 | c.5247C>T p.L1749= | Silent (SNP) | VAF 35/41 reads (85%) | catalogued as rs767001317, COSV60548155; called by muse, mutect2, varscan2
- FZD5 | c.72G>A p.A24= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1180071257, COSV99776391; called by muse, mutect2, varscan2
- GLB1L2 | c.1740C>T p.G580= | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as rs750442136, COSV56995544; called by muse, mutect2, varscan2
- GPR34 | c.277C>T p.L93= | Silent (SNP) | VAF 83/149 reads (56%) | catalogued as COSV100587734, COSV59363143; called by muse, mutect2, varscan2
- HCAR2 | c.696C>T p.F232= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100186528; called by muse, varscan2
- HCAR3 | c.696C>T p.F232= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100811637; called by muse, mutect2, varscan2
- HELZ2 | c.3891C>T p.L1297= (on ENST00000467148 / NM_001037335.2; = p.L728= on NM_033405.3) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV71295547; called by muse, mutect2, varscan2
- HLA-DQB1 | c.396C>A p.T132= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs759515947, COSV66569639; called by muse, mutect2, varscan2
- IGHV1-18 | c.315G>C p.L105= | Silent (SNP) | VAF 242/526 reads (46%) | catalogued as rs541025015; called by muse, mutect2, varscan2
- INTS1 | c.972C>T p.S324= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs764463716, COSV67176627; called by muse, mutect2, varscan2
- LDLRAD3 | c.936G>C p.L312= | Silent (SNP) | VAF 69/87 reads (79%) | catalogued as COSV59679560; called by muse, mutect2, varscan2
- LY6H | c.87G>A p.Q29= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV61370451, COSV61371442; called by muse, mutect2, varscan2
- MEGF10 | c.402C>T p.N134= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV57245936; called by muse, mutect2, varscan2
- MRC1 | c.1962T>C p.S654= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- MYO1E | c.2925C>A p.P975= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV55683500; called by muse, mutect2, varscan2
- NANOG | c.435C>T p.N145= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs775613887, COSV57550993; called by muse, varscan2
- NDUFA9 | c.1041C>G p.L347= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1283350619, COSV56928015; called by muse, mutect2, varscan2
- NEDD4 | c.159C>T p.P53= | Silent (SNP) | VAF 58/105 reads (55%) | catalogued as COSV59059443; called by muse, mutect2, varscan2
- NFATC2 | c.2136G>C p.P712= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV65353806; called by muse, mutect2, varscan2
- NUP214 | c.1686G>A p.V562= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV63910750; called by muse, mutect2
- NYNRIN | c.4251C>T p.L1417= | Silent (SNP) | VAF 41/52 reads (79%) | catalogued as COSV66841458; called by muse, mutect2, varscan2
- NYNRIN | c.4542C>T p.L1514= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV66841461; called by muse, mutect2, varscan2
- OR12D3 | c.249C>A p.L83= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV65826744; called by muse, mutect2
- OR14K1 | c.729C>T p.L243= | Silent (SNP) | VAF 33/35 reads (94%) | catalogued as rs760698783, COSV51720649; called by muse, mutect2, varscan2
- OR4C3 | c.627C>T p.F209= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as rs141730559, COSV60584169; called by muse, mutect2, varscan2
- OR6C1 | c.474C>G p.L158= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV65572842; called by muse, mutect2, varscan2
- PAN2 | c.1191C>T p.L397= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as COSV57753035; called by muse, mutect2, varscan2
- PDLIM5 | c.864G>A p.Q288= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs770979082, COSV58745952; called by muse, mutect2, varscan2
- PROX2 | c.678G>C p.L226= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV71519986; called by muse, mutect2, varscan2
- PRUNE2 | c.7692G>A p.E2564= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as COSV65038719; called by muse, mutect2, varscan2
- PTPN21 | c.1956C>G p.L652= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs1342897909, COSV60846272; called by muse, mutect2, varscan2
- RADIL | c.2541G>A p.P847= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs769324009, COSV101271457; called by muse, varscan2
- RBM8A | c.339G>A p.L113= | Silent (SNP) | VAF 102/111 reads (92%) | catalogued as COSV57161989; called by muse, varscan2
- RIPOR1 | c.897C>G p.P299= (on ENST00000379312 / NM_001193522.2; = p.P295= on NM_024519.4) | Silent (SNP) | VAF 6/107 reads (6%) | catalogued as COSV50218055; called by muse, mutect2
- RNF34 | c.492G>T p.L164= | Silent (SNP) | VAF 98/208 reads (47%) | catalogued as COSV63442079; called by muse, mutect2, varscan2
- SCRN2 | c.903C>T p.C301= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs766077281, COSV51635113; called by muse, mutect2, varscan2
- SLC16A9 | c.909C>T p.N303= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV68098495, COSV68098962; called by muse, mutect2, varscan2
- SLC6A1 | c.1554G>A p.Q518= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV55113756; called by muse, mutect2, varscan2
- SNAP47 | c.48G>A p.P16= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs1202049527, COSV59917201; called by muse, mutect2, varscan2
- SYTL4 | c.1914A>G p.E638= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV52165953; called by muse, mutect2, varscan2
- TCTN1 | c.1704C>T p.F568= (on ENST00000551590 / NM_001173975.3; = p.F554= on NM_024549.6) | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV54371442; called by muse, mutect2, varscan2
- TERF2 | c.1185G>A p.K395= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as COSV54746789; called by muse, mutect2, varscan2
- TIAM2 | c.414C>T p.L138= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV59690673; called by muse, mutect2, varscan2
- TRIM51 | c.948A>G p.Q316= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV55264571; called by muse, mutect2, varscan2
- TRPV4 | c.1833C>T p.F611= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV55680832; called by muse, mutect2, varscan2
- TYRO3 | c.1848C>T p.L616= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs377341711; called by muse, mutect2, varscan2
- WNT9B | c.1062C>T p.T354= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV51517677; called by muse, mutect2, varscan2
- ZNF774 | c.498C>T p.L166= | Silent (SNP) | VAF 55/93 reads (59%) | catalogued as COSV62979688; called by muse, mutect2, varscan2
- ABCA2 | chr9:137033074 del G | 5'Flank (DEL) | VAF 18/70 reads (26%) | catalogued as rs1564241094; called by mutect2, pindel
- ACSS2 | chr20:34875128 G>T | 5'Flank (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- AL133373.3 | n.801G>A | RNA (SNP) | VAF 10/38 reads (26%) | catalogued as rs1167611863; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73829129 G>A | 3'Flank (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2099G>A | Intron (SNP) | VAF 36/89 reads (40%) | catalogued as COSV57919306; called by muse, mutect2, varscan2
- MIR124-2 | n.3C>G | RNA (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- NBPF7 | n.487G>A | RNA (SNP) | VAF 67/151 reads (44%) | called by muse, mutect2, varscan2
